Gene-level copy-number profile of tumor specimen TCGA-85-A53L-01A from TCGA case TCGA-85-A53L, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Middle lobe, lung; AJCC pathologic stage: Stage IIA; Age at diagnosis: 63.1 years (23,065 days).
Specimen TCGA-85-A53L-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.76aab070-cabe-4e70-abce-a0f75c3e496a.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-85-A53L-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/4a926f8b-5302-4882-a594-e40de947aa8e

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 77; copy number 1: 18; copy number 2: 23,748; copy number 3: 7,946; copy number 4: 18,100; copy number 5: 3,460; copy number 6: 3,668; copy number 7: 1,783; copy number 8: 453; copy number 9: 86; copy number 11: 132; copy number 12: 92; copy number 13: 23; copy number 14: 20; copy number 18: 14; copy number 20: 21; copy number 21: 72; copy number 24: 84; copy number 32: 22.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-85-A53L-01A-21D-A26L-01): tumor purity 0.43, ploidy 1.75, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 77 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:10,210,570–10,381,603, 1 gene (within-gene range 0–2): KIF1B.
- chr1:10,298,966–10,796,650, 16 genes: RNU6-37P, RN7SL731P, AL139424.3, AL139424.2, PGD, AL139424.1, CENPS-CORT, CENPS, CORT, DFFA, AL354956.1, PEX14, AL139423.2, RN7SL614P, CASZ1, AL139423.1.
- chr9:20,502,265–22,128,103, 60 genes: MIR4474, AL163193.1, FOCAD, FOCAD-AS1, MIR491, SNORA30B, HACD4, IFNNP1, IFNB1, IFNWP4, AL390882.1, IFNW1, Y_RNA, IFNA21, IFNWP15, IFNA4, IFNWP9, IFNA7, IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9,930 genes in 28 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:119,140,391–189,133,292, 1,434 genes, copy number 6–13 (broad region; genes not listed).
- chr2:3,703,575–65,056,168, 998 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr2:234,438,328–237,912,106, 49 genes, copy number 5 (within-gene range 2–5): AC097713.1, LINC01891, HSPE1P9, ARL4C, LINC01173, AC104394.1, AC010148.1, SH3BP4, AC114814.1, CEP19P1, AC114814.2, AGAP1, AGAP1-IT1, AC064874.1, TMSB10P1, RNU7-127P, RN7SL204P, Y_RNA, GBX2, AC019068.1, ASB18, RNU1-31P, IQCA1, AC093915.1, IQCA1-AS1, RPL3P5, ACKR3, AC084030.1, AC012063.1, RNU6-1051P, AC105760.1, COPS8, AC107079.1, AC112715.1, COL6A3, AC112721.1, AC112721.2, MLPH, MIR6811, RNU6-1140P, PRLH, RAB17, AC104667.2, AC104667.1, LRRFIP1, AC012076.1, RBM44, RAMP1, SNORD39.
- chr3:84,958,989–90,257,415, 42 genes, copy number 5 (within-gene range 2–5): CADM2, MIR5688, CADM2-AS2, CADM2-AS1, THAP12P2, AC107024.1, RNU6-1129P, AC108733.1, RN7SKP284, LINC02070, AC108706.1, VGLL3, PPATP1, LINC00506, MIR4795, CHMP2B, POU1F1, KRT8P25, APOOP2, PSMC1P6, AC108749.1, RNU6-873P, HTR1F, RNU6ATAC6P, CGGBP1, AC119733.1, ZNF654, CBX5P1, C3orf38, ABCF2P1, CSNKA2IP, Y_RNA, NDUFA5P5, ICE2P2, GAPDHP50, EPHA3, AC109129.1, MTCO2P6, MTCO1P6, U3, RNU6-712P, PROS2P.
- chr3:104,502,700–198,222,513, 1,659 genes, copy number 6–32 (broad region; genes not listed).
- chr5:58,198–4,147,429, 95 genes, copy number 5 (broad region; genes not listed).
- chr6:18,363,417–19,839,080, 10 genes, copy number 5 (within-gene range 3–5): DDX18P3, IMPDH1P9, RNF144B, MIR548A1HG, MIR548A1, AL589647.1, AL357052.1, LNC-LBCS, RPL5P20, RNA5SP205.
- chr6:128,761,717–132,273,332, 45 genes, copy number 5: Y_RNA, LAMA2, MESTP1, BMPR1AP1, RNU6-861P, AL356124.1, AL356124.2, ARHGAP18, RPL5P21, AL451046.2, B3GALNT2P1, AL451046.1, TMEM244, L3MBTL3, AL355581.1, SAMD3, TMEM200A, Y_RNA, AL583803.1, SMLR1, EPB41L2, AKAP7, AL137222.1, RPL21P67, ARG1, MED23, ENPP3, RNU4-18P, OR2A4, CTAGE9, AC005587.1, MIR548H5, ENPP1, SELENOKP2, RN7SKP245, AL139805.1, AL117378.1, AL117378.2, CCN2, AL133346.1, AL021408.1, MIR548AJ1, AL021408.2, LINC01013, EEF1A1P36.
- chr7:70,972–109,326,315, 2,042 genes, copy number 5–9 (broad region; genes not listed).
- chr8:9,555,912–10,428,891, 10 genes, copy number 12 (within-gene range 2–12): TNKS, AC103834.1, MIR597, MIR124-1HG, MIR124-1, AC034111.2, AC034111.1, MSRA, AC023385.1, AC079200.1.
- chr8:35,235,475–36,191,194, 7 genes, copy number 13 (within-gene range 2–13): UNC5D, AC090740.1, LSM12P1, AC105230.1, AC124290.1, AC124290.2, AC124290.3.
- chr8:36,784,324–36,936,125, 1 gene, copy number 21 (within-gene range 2–21): KCNU1.
- chr8:36,887,456–39,310,443, 71 genes, copy number 21 (broad region; genes not listed).
- chr8:79,891,553–83,294,271, 70 genes, copy number 7 (within-gene range 4–7) (broad region; genes not listed).
- chr8:105,546,089–145,066,685, 584 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr9:103,361,952–107,171,148, 53 genes, copy number 6: AL390962.1, RNA5SP291, AL590381.1, SMC2-AS1, SMC2, TOPORSLP, AL512646.1, OR13F1, AL450426.1, OR13C4, OR13C3, OR13C8, OR13D2P, OR13C5, OR13C2, OR13C9, OR13I1P, OR13C1P, OR13D1, OR13D3P, NIPSNAP3A, NIPSNAP3B, ABCA1, AL359182.1, CT70, AL591506.1, RN7SKP191, SLC44A1, FSD1L, RALGAPA1P1, AL158070.1, FKTN, AL158070.2, TAL2, TMEM38B, AL592437.1, DEPDC1P2, SLC25A6P5, LINC01505, AL732323.1, AL451140.1, MIR8081, AL512649.2, RN7SKP77, AL512649.1, RNA5SP292, ZNF462, AL807761.4, AL512593.1, AL807761.1, AL807761.2, AL807761.3, AL445487.1.
- chr11:98,565,074–102,084,554, 22 genes, copy number 6: AP003038.1, AP003715.1, AP002428.1, CNTN5, RN7SKP53, RPA2P3, RN7SL222P, PPIAP43, ARHGAP42-AS1, ARHGAP42, RN7SKP115, PGR, PGR-AS1, AP001533.1, TRPC6, MIR3920, AP003080.1, AP000776.1, ANGPTL5, CEP126, CFAP300, RNA5SP535.
- chr12:66,767–25,250,936, 656 genes, copy number 7 (broad region; genes not listed).
- chr14:18,333,726–20,641,691, 133 genes, copy number 5–8 (broad region; genes not listed).
- chr14:63,298,126–66,509,394, 76 genes, copy number 5–8 (broad region; genes not listed).
- chr16:35,021,749–57,487,327, 371 genes, copy number 6–8 (broad region; genes not listed).
- chr17:69,355,133–83,095,122, 479 genes, copy number 5 (broad region; genes not listed).
- chr18:29,629,842–31,162,856, 12 genes, copy number 5: AC117569.2, AC115100.1, MIR302F, AC090506.1, AC090506.2, AC016382.1, RNU6-857P, DSC3, DSC2, DSCAS, DSC1, AC012417.1.
- chr19:17,719,242–30,016,612, 369 genes, copy number 5–18 (within-gene range 4–18) (broad region; genes not listed).
- chr20:60,812,004–64,313,132, 147 genes, copy number 6 (broad region; genes not listed).
- chr22:22,201,663–33,058,381, 475 genes, copy number 5–8 (within-gene range 2–8) (broad region; genes not listed).
- chr22:39,743,044–39,893,864, 1 gene, copy number 14 (within-gene range 1–14): ENTHD1.
- chr22:39,874,255–40,674,451, 19 genes, copy number 14: RN7SKP210, UQCRFS1P1, GRAP2, Z82206.1, FAM83F, Z83847.1, TNRC6B, RPL7P52, ADSL, AL022238.3, SGSM3, SGSM3-AS1, MRTFA, AL022238.2, AL022238.1, MRTFA-AS1, COX6B1P3, RPL4P6, GAPDHP37.

Autosomal genes at a single copy (total copy number 1): 14. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
